CCDI case PBBUDY — CCDI-MCI: Molecular Characterization Initiative (MCI)
Open-access clinical record from the NCI Genomic Data Commons (Data Release 46.0 - August 10, 2026). Disease type: Neoplasms, NOS; Primary site: Ovary.
https://portal.gdc.cancer.gov/cases/3a9ea045-2d94-4d9d-bc20-ea8bdcd0d179

Demographics
Sex at birth: female; Race: white; Vital status: Alive.

Diagnoses (1)
1. Sertoli cell tumor, NOS: ICD-O-3 morphology code: 8640/1; Tissue or organ of origin: Ovary; Age at diagnosis: 14.3 years (5,205 days).

Biospecimens (3 samples)
- Sample 0DH6ZW: Tissue type: Normal; Specimen type: Peripheral Whole Blood.
- Sample 0DH72Z: Tissue type: Tumor; Specimen type: Solid Tissue; Preservation method: FFPE.
- Sample 0DHV60: Tissue type: Tumor; Specimen type: Solid Tissue.
